Somatic mutation profile of tumor specimen MP2PRT-PARBMC-TMP1-A (aliquot MP2PRT-PARBMC-TMP1-A-1-0-D-A83B-36) from MP2PRT case MP2PRT-PARBMC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Precursor B-cell lymphoblastic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.8 years (1,401 days).
Specimen MP2PRT-PARBMC-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1fe18c36-d018-4c75-892b-25b057216cda.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARBMC-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARBMC-NB1-A-1-0-D-A83B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/442ab06a-b0be-476a-b74f-c7a411abd349

The open-access MAF lists 33 somatic variants for this specimen: 24 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 8, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AREG | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 48/217 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as rs1219113338; called by muse, mutect2, varscan2
- ATP6V1H | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 102/252 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746947272; called by muse, mutect2, varscan2
- BASP1 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 46/606 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs1442362061; called by muse, mutect2
- BMP15 | c.617G>T p.R206L | Missense Mutation (SNP) | VAF 56/373 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.247); catalogued as CM061657; called by muse, mutect2, varscan2
- CROCC2 | c.3601C>T p.R1201W | Missense Mutation (SNP) | VAF 242/548 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs766416180; called by muse, varscan2
- DNAH7 | c.9815G>A p.R3272Q | Missense Mutation (SNP) | VAF 25/162 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778417940, COSV56786798; called by muse, mutect2, varscan2
- DOCK5 | c.3574G>A p.V1192I | Missense Mutation (SNP) | VAF 161/342 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as rs1445798159; called by muse, mutect2, varscan2
- FANCD2OS | c.106T>C p.S36P | Missense Mutation (SNP) | VAF 174/473 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.151); catalogued as COSV67556371; called by muse, mutect2, varscan2
- FLT3 | c.1988A>G p.K663R | Missense Mutation (SNP) | VAF 66/371 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV54044253; called by muse, mutect2, varscan2
- GPRC6A | c.778C>T p.R260W | Missense Mutation (SNP) | VAF 105/412 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as rs754816180, COSV59954746, COSV59955335; called by muse, mutect2, varscan2
- HTR2C | c.790C>A p.L264M | Missense Mutation (SNP) | VAF 111/877 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.784); catalogued as COSV52217548; called by muse, mutect2, varscan2
- MAGEB4 | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 100/414 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.866); catalogued as rs1043294170, COSV64397382; called by muse, mutect2, varscan2
- MUC16 | c.3656C>T p.P1219L | Missense Mutation (SNP) | VAF 202/462 reads (44%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.053); catalogued as rs370098137; called by muse, mutect2, varscan2
- PCDHGA2 | c.1984G>A p.V662M | Missense Mutation (SNP) | VAF 323/747 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.866); catalogued as rs754195555, COSV53947328; called by muse, mutect2, varscan2
- STXBP5 | c.725C>T p.S242F | Missense Mutation (SNP) | VAF 60/207 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51653162; called by muse, mutect2, varscan2
- TTN | c.97859C>A p.T32620N (on ENST00000591111; = p.T25196N on NM_003319.4) | Missense Mutation (SNP) | VAF 74/394 reads (19%) | PolyPhen probably damaging (0.997); catalogued as rs985229219; called by muse, mutect2, varscan2
- ZNF544 | c.991C>T p.R331C | Missense Mutation (SNP) | VAF 155/328 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs370170869; called by muse, mutect2, varscan2
- ABCA4 | c.2159T>C p.M720T | Missense Mutation (SNP) | VAF 43/259 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2
- CCDC158 | c.355C>A p.L119I | Missense Mutation (SNP) | VAF 96/230 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by mutect2, varscan2
- CFAP54 | c.9226C>G p.L3076V | Missense Mutation (SNP) | VAF 70/199 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.325); called by muse, mutect2
- KCNC1 | c.844G>A p.D282N | Missense Mutation (SNP) | VAF 219/463 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PNMA6A | c.576G>T p.E192D | Missense Mutation (SNP) | VAF 81/199 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- SLC5A8 | c.476G>C p.G159A | Missense Mutation (SNP) | VAF 24/408 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); called by muse, mutect2
- YAP1 | c.1415C>T p.P472L (on ENST00000282441 / NM_001130145.3; = p.P418L on NM_006106.5) | Missense Mutation (SNP) | VAF 183/350 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CD177 | c.1116C>T p.C372= | Silent (SNP) | VAF 43/275 reads (16%) | catalogued as rs201285428; called by muse, varscan2
- CROCC2 | c.3600C>T p.A1200= | Silent (SNP) | VAF 242/544 reads (44%) | called by muse, varscan2
- CTNNA2 | c.1677G>A p.E559= | Silent (SNP) | VAF 188/388 reads (48%) | called by muse, mutect2, varscan2
- HSPG2 | c.5727G>A p.A1909= | Silent (SNP) | VAF 203/411 reads (49%) | catalogued as rs1440296484; called by muse, mutect2, varscan2
- NATD1 | c.240C>T p.F80= | Silent (SNP) | VAF 161/559 reads (29%) | catalogued as rs779493539, COSV101204705; called by muse, mutect2, varscan2
- PCDHA2 | c.156G>T p.L52= | Silent (SNP) | VAF 113/645 reads (18%) | called by muse, mutect2, varscan2
- TDRD6 | c.1599A>G p.V533= | Silent (SNP) | VAF 83/655 reads (13%) | called by muse, mutect2, varscan2
- URGCP | c.1359C>T p.H453= (on ENST00000453200 / NM_001077663.3; = p.H444= on NM_017920.4) | Silent (SNP) | VAF 193/424 reads (46%) | catalogued as rs547811720, COSV56245973; called by muse, mutect2, varscan2
- FGFR3 | c.*867G>A | 3'UTR (SNP) | VAF 60/323 reads (19%) | called by muse, mutect2, varscan2
